Somatic mutation profile of tumor specimen TARGET-50-PAJPCM-01A (aliquot TARGET-50-PAJPCM-01A-01D) from TARGET case TARGET-50-PAJPCM, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: female; Vital status: Alive; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 4.8 years (1,754 days).
Specimen TARGET-50-PAJPCM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b7a8c20-d2ad-47e1-a19a-f78e12fadd45.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PAJPCM-10A (Blood Derived Normal), aliquot TARGET-50-PAJPCM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/115e2659-952b-4634-9ae7-9302a3296152

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 8, Silent 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.920-2del p.X307_splice | Splice Site (DEL) | VAF 49/70 reads (70%) | hotspot (GDC flag); catalogued as COSV52693974, COSV52706655, COSV52945558, COSV53066011; called by mutect2, pindel, varscan2
- FAM111A | c.1140T>G p.I380M | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64655387; called by muse, mutect2, varscan2
- GTF2IRD1 | c.889G>A p.G297S | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs782267935, COSV56086666; called by muse, mutect2, varscan2
- IFNA4 | c.230T>C p.I77T | Missense Mutation (SNP) | VAF 138/148 reads (93%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.843); catalogued as COSV101426985; called by muse, mutect2
- KLF3 | c.194C>T p.T65M | Missense Mutation (SNP) | VAF 4/73 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV54710978; called by muse, mutect2
- ODF1 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53433731; called by muse, mutect2, varscan2
- SH2D2A | c.991C>A p.P331T | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV63884977; called by muse, mutect2, varscan2
- STAU1 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 286/630 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs753513004; called by muse, mutect2, varscan2
- ZNF469 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs940155253, COSV71259373; called by muse, mutect2, varscan2
- SLC22A13 | c.300C>T p.S100= | Silent (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- SLC5A2 | c.1254C>T p.G418= | Silent (SNP) | VAF 11/31 reads (35%) | called by muse, mutect2, varscan2
- ZBED4 | c.2307G>T p.L769= | Silent (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
